Gene-level copy-number profile of tumor specimen TARGET-40-0A4HMC-01A from TARGET case TARGET-40-0A4HMC, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 27.9 years (10,205 days).
Specimen TARGET-40-0A4HMC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.c453dc5a-3f40-57a4-953d-ad09821ecaf8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4HMC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 407 have no estimate.
https://portal.gdc.cancer.gov/files/51233ea5-9bfd-41e2-844b-986bc20810ca

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2,395; copy number 1: 585; copy number 2: 283; copy number 3: 19,399; copy number 4: 16,031; copy number 5: 11,590; copy number 6: 4,032; copy number 7: 3,775; copy number 8: 1,219; copy number 9: 792; copy number 12: 104; copy number 13: 9; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,616,137, 4 genes: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr4:179,069,437–180,117,163, 5 genes: AC018710.1, AC020551.1, AC021193.1, AC108169.1, AC096747.1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:21,000,881–21,284,955, 4 genes: RNA5SP336, AC090857.1, AC090857.2, AC099730.1.
- chr11:55,662,201–55,674,675, 2 genes (within-gene range 0–4): OR4C6, OR4V1P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,849 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:103,362,082–106,996,534, 71 genes, copy number 7 (broad region; genes not listed).
- chr2:237,966,827–242,160,153, 123 genes, copy number 7 (broad region; genes not listed).
- chr3:145,684,572–146,495,991, 12 genes, copy number 12–15: GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2.
- chr6:167,607–58,438,364, 1,527 genes, copy number 7–9 (within-gene range 7–12) (broad region; genes not listed).
- chr8:150,584–2,165,552, 48 genes, copy number 7–8: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.
- chr8:39,584,489–88,328,025, 733 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:104,590,733–105,804,539, 1 gene, copy number 7 (within-gene range 1–7): ZFPM2.
- chr8:105,142,860–139,704,109, 380 genes, copy number 7–8 (broad region; genes not listed).
- chr8:139,911,238–140,041,037, 3 genes, copy number 7: AC021744.1, C8orf17, AC040978.1.
- chr14:23,511,760–89,111,223, 1,169 genes, copy number 7 (broad region; genes not listed).
- chr14:89,156,743–89,291,594, 2 genes, copy number 7: AL138478.1, CAP2P1.
- chr14:89,355,060–89,356,571, 1 gene, copy number 7: AL357093.1.
- chr14:96,039,362–99,604,207, 56 genes, copy number 7 (within-gene range 6–7): C14orf132, BDKRB2, AL355102.2, AL355102.1, CKS1BP1, AL355102.5, BDKRB1, AL355102.4, AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA, AL137786.1, RN7SKP108, AL137786.2, LINC02299, AL137786.3, VRK1, LINC00618, AL049833.3, AL049833.4, AL049833.2, AL049833.1, LINC02304, AL158800.1, LINC02325, LINC02291, AL163872.1, LINC02312, AL355097.1, LINC01550, AL163932.1, LINC02295, RN7SL714P, AL132719.1, C14orf177, AL132796.1, AL132796.3, AL132796.2, RPL3P4, AL162151.2, AL162151.3, AL162151.1, BCL11B, AL109767.1, AL132819.1, SETD3, RNU6-91P, CCNK, CCDC85C, AL110504.1.
- chr14:105,785,505–106,369,546, 103 genes, copy number 12 (broad region; genes not listed).
- chr15:80,195,481–99,498,375, 464 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr16:77,590,806–78,066,761, 12 genes, copy number 9: LINC02131, AC092724.1, NUDT7, AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr16:78,123,243–78,355,834, 5 genes, copy number 9: AC079414.3, AC009044.1, WWOX-AS1, AC106743.1, LSM3P5.
- chr17:54,609,249–57,684,689, 48 genes, copy number 7 (within-gene range 4–7): AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG, C17orf67, AC106858.1, DGKE, TRIM25, RNU6-1158P, AC015912.2, AC015912.1, MIR3614, AC015912.3, COIL, AC004584.1, AC004584.2, SCPEP1, AC004584.3, RNF126P1, AC007114.1, AKAP1, AC007114.2, AC003950.1, AC091181.2, MSI2, AC091181.1, AC015883.1.
- chr17:57,685,529–72,237,203, 402 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr18:24,500,399–37,565,827, 180 genes, copy number 7 (broad region; genes not listed).
- chr20:30,323,367–48,367,976, 509 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 172. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
